Gene-level copy-number profile of tumor specimen TCGA-CQ-7064-01A from TCGA case TCGA-CQ-7064, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Mouth, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 83.9 years (30,640 days).
Specimen TCGA-CQ-7064-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.0ae043e4-c971-4502-84e7-76840d96388f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CQ-7064-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9b3d6139-0cd1-4403-ad19-86f84fb1ecf1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 7,074; copy number 2: 47,687; copy number 3: 4,873; copy number 5: 160; copy number 10: 26.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CQ-7064-01A-11D-2390-01): tumor purity 0.4, ploidy 1.87, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 186 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:32,293,558–34,134,696, 75 genes, copy number 5 (broad region; genes not listed).
- chr9:34,191,555–34,191,881, 1 gene, copy number 5: RPL35AP2.
- chr18:20,946,906–26,391,685, 110 genes, copy number 5–10 (within-gene range 1–10) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 5,716. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
